Surgical pathology report (de-identified scan), TCGA case TCGA-J4-A83L, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site ABS - Lahey Clinic, specimen TCGA-J4-A83L-01A (Primary Tumor).

[page 1 of 5]
MRN
Name
Encounter Number

Gender
Date Of Birth

COPY ONLY DO NOT FILE

SURGICAL PATHOLOGY

Time Collected
Time Reported
Ordering Provider
Status

Time Received
Order Number

Results

Final

Source of Specimen

- A. LEFT OBTURATOR LYMPH NODE FS-
- B. LEFT OBTURATOR LYMPH NODE NFS-
- C. RIGHT OBTURATOR LYMPH NODE FS-
- D. RIGHT OBTURATOR LYMPH NODE NFS-
- E. PROSTATE, SEMINAL VESICLE, VAS DEFERENS-

FINAL DIAGNOSIS:

- A. LEFT OBTURATOR LYMPH NODE FS-
TWO REACTIVE LYMPH NODES, NO TUMOR SEEN, 0/2.
- B. LEFT OBTURATOR LYMPH NODE NFS-
TWO REACTIVE LYMPH NODES, NO TUMOR SEEN, 0/2.
- C. RIGHT OBTURATOR LYMPH NODE FS-
ONE REACTIVE LYMPH NODE, NO TUMOR SEEN, 0/1.
- D. RIGHT OBTURATOR LYMPH NODE NFS-
THREE REACTIVE LYMPH NODES, NO TUMOR SEEN, 0/3.
- E. PROSTATE, SEMINAL VESICLE, VAS DEFERENS-
ADENOCARCINOMA OF PROSTATE. NO EXTRAPROSTATIC EXTENSION SEEN.

TUMOR SITE: RIGHT GREATER THAN LEFT , MOSTLY IN MID ZONE.

SPECIMEN TYPE: RADICAL PROSTATECTOMY.

WEIGHT: 73 GRAMS. SIZE: 5.5 x 4.5 x 4 CM.

GLEASON SCORE (PRIMARY + SECONDARY PATTERN): 3 + 4 = 7/10.

TERTIARY PATTERN: IS NOT PRESENT.

copy ICD-O-3
path Adenocarcinoma acinar 8140/3
Adenocarcinoma NOS 8140/3
Site Prostate NOS C61.9
J 11/24/13

[page 2 of 5]
SEVERITY IN EXTENT OF TUMOR: 4/5.

(1: <5%; 2: 5-15%; 3: 15-30%; 4: 30-50%; 5: > 50% tissue involvement).

DOMINANT NODULE (AT LEAST 1 CM IN SIZE): IS PRESENT, 1 CM IN SIZE.

TREATMENT EFFECT ON CARCINOMA: NOT IDENTIFIED.

TNM STAGE: AT LEAST pT2c, pN0, pMX.

LYMPHATIC (SMALL VESSEL) INVASION: IS NOT SEEN.

PERINEURAL INVASION: IS NOT PRESENT.

NO TUMOR SEEN IN SEMINAL VESICLES.

MARGIN STATUS:

TUMOR IS CLOSE TO BUT DOES NOT INVOLVE THE ANTERIOR-SUPERIOR CAPSULAR MARGIN (E13). ALL OTHER MARGINS ARE CLEAR.

[REDACTED]

Signed Others

Frozen Section

A. LEFT OBTURATOR LYMPH NODE, FS: TWO LYMPH NODES WITH NO TUMOR SEEN.

RIGHT OBTURATOR LYMPH NODE, FS: ONE LYMPH NODE WITH NO TUMOR SEEN.

Frozen section performed [REDACTED]

Case Clinical Information

PROSTATE CANCER

Gross Description

A. Received in formalin labeled with the patient's name and "left obturator lymph node-FS" are two gray/tan fibrofatty frozen section tissue fragments. The larger measures 1.7 x 0.6 cm; the smaller, 1.3 x 1 cm. Entirely submitted in A1.

B. Received in formalin labeled with the patient's name and "left obturator lymph node-NFS" is a yellow fibrofatty tissue

[REDACTED]

[page 3 of 5]
fragment measuring 3.5 x 2.5 cm. The fat is trimmed. No probable lymph nodes are grossly identified. The specimen is submitted complete in B1-B3.

C. Received in formalin labeled with the patient's name and "right obturator lymph node-FS" is a gray/tan frozen section tissue fragment measuring 1.5 x 1 cm in greater dimensions. Entirely submitted in C1.

D. Received in formalin labeled with the patient's name and "right obturator lymph node-NFS" is a yellow fibrofatty tissue fragment measuring 2 x 2 cm. No lymph nodes are grossly identified. Entirely submitted in D1, D2.

E. Received in formalin labeled "prostate, seminal vesicle and vas deferens" is a radical prostatectomy specimen which includes a 73 gram prostate gland with attached seminal vesicle and vas deferens. The prostate gland measures 5.5 x 4.5 x 4 cm and has a shaggy capsule that is disrupted at the bladder resection margin and has been previously inked black on the left and blue on the right. The right seminal vesicle measures 2 x 1.5 cm. The right vas measures 2.5 x 0.5 cm. The left seminal vesicle measures 2.5 x 1.5 cm. The left vas measures 2.5 x 0.5 cm. The inferior prostate is sectioned transversely, removed from the rest of the specimen and sectioned from anterior to posterior following the plane of the urethra. The remaining gland is serially sectioned transversely and shows a firm, focally nodular parenchyma. The seminal vesicles and vasa deferentia show no abnormalities. Representative sections submitted as follows: inferior prostate demonstrating apical margin submitted entirely anterior to posterior in E1-E6; bladder resection margin, shaved and serially sectioned in E7, E8; complete section of mid gland anterior in E9, E10; posterior in E11, E12; complete section of upper third of gland, anterior in E13, E14; posterior in E15, E16; remainder of the posterior gland entirely submitted in E17-E22; right seminal vesicle and vas deferens in E23; and left seminal vesicle and vas deferens in E24.

Procedure

- A. AA ROUTINE H&E X1 BLOCK
H&E X1
- B. AA ROUTINE H&E X1 BLOCK.1
H&E X1
- B. AA ROUTINE H&E X1 BLOCK.2
H&E X1
- B. AA ROUTINE H&E X1 BLOCK.3

[page 4 of 5]
H&E X1
C. AA ROUTINE H&E X1 BLOCK
H&E X1
D. AA ROUTINE H&E X1 BLOCK.1
H&E X1
D. AA ROUTINE H&E X1 BLOCK.2
H&E X1
E. AA ROUTINE H&E X1 BLOCK.1
H&E X1
E. AA ROUTINE H&E X1 BLOCK.2
H&E X1
E. AA ROUTINE H&E X1 BLOCK.3
H&E X1 AA RECUT
E. AA ROUTINE H&E X1 BLOCK.4
H&E X1
E. AA ROUTINE H&E X1 BLOCK.5
H&E X1
E. AA ROUTINE H&E X1 BLOCK.6
H&E X1
E. AA ROUTINE H&E X1 BLOCK.7
H&E X1 AA RECUT
E. AA ROUTINE H&E X1 BLOCK.8
H&E X1 AA RECUT
E. AA ROUTINE H&E X1 BLOCK.9
H&E X1
E. AA ROUTINE H&E X1 BLOCK.10
H&E X1 A RECUTS
E. AA ROUTINE H&E X1 BLOCK.11
H&E X1
E. AA ROUTINE H&E X1 BLOCK.12
H&E X1 A RECUTS
E. AA ROUTINE H&E X1 BLOCK.13
H&E X1 A RECUTS
E. AA ROUTINE H&E X1 BLOCK.14
H&E X1,
E. AA ROUTINE H&E X1 BLOCK.15
H&E X1
E. AA ROUTINE H&E X1 BLOCK.16
H&E X1 A RECUTS
E. AA ROUTINE H&E X1 BLOCK.17
H&E X1
E. AA ROUTINE H&E X1 BLOCK.18
H&E X1
E. AA ROUTINE H&E X1 BLOCK.19
H&E X1
E. AA ROUTINE H&E X1 BLOCK.20
H&E X1
E. AA ROUTINE H&E X1 BLOCK.21
H&E X1

[page 5 of 5]
E. AA ROUTINE H&E X1 BLOCK.22
H&E X1
E. AA ROUTINE H&E X1 BLOCK.23
H&E X1
E. AA ROUTINE H&E X1 BLOCK.24
H&E X1

Criteria	W 10/9/13	Yes	No

Source: NCI Genomic Data Commons file e615ef9c-00cf-4c90-9ab4-f6adb054343b (TCGA-J4-A83L.837A4811-0DAF-46F6-9C84-D2BBFFC56AF0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).